MMRF case MMRF_2007 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/fd4114d1-abf7-43ae-9da8-6fcf0ab26386

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.8 years (24,410 days); ISS stage: II; Days to last known disease status: 1,029 days (2.8 years); Days to last follow up: 1,029 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 101 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 112 days; Days to treatment end: 112 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 151 days; Days to treatment end: 152 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 154 days; Days to treatment end: 154 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 436 days (1.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 6.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 104 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 4.4 µg/mL; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 4.84 mmol/L; Leukocytes 5.16 ×10⁹/L; Absolute Neutrophil 2.59 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 102 µmol/L; Calcium 2.15 mmol/L; Albumin 27 g/L; Total Protein 11.5 g/dL; Glucose 5.2 mmol/L; C-Reactive Protein 0.096 mg/dL.
- Day 87 (ECOG 0): M Protein 2.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 57.8 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 1.77 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 3.74 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 69 µmol/L; Calcium 2.25 mmol/L; Albumin 32 g/L; Total Protein 8.3 g/dL; Glucose 5.4 mmol/L.
- Day 211 (ECOG 0): M Protein 9 g/dL; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.38 ×10⁹/L; Absolute Neutrophil 1.26 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 64 µmol/L; Calcium 2.19 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 5 mmol/L.
- Day 274 (ECOG 0): M Protein 6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.74 mg/dL; Immunoglobulin G 16.3 g/L; Immunoglobulin A 4.42 g/L; Immunoglobulin M 0.81 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.09 ×10⁹/L; Absolute Neutrophil 2.76 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 87 µmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 5.6 mmol/L.
- Day 367 (ECOG 0): M Protein 6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.5 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 4.03 g/L; Immunoglobulin M 0.85 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 1.88 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 68 µmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 5.4 mmol/L.
- Day 476 (ECOG 0): M Protein 5.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.52 mg/dL; Immunoglobulin G 15.5 g/L; Immunoglobulin A 4.9 g/L; Immunoglobulin M 0.62 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.11 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 88 µmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 4.8 mmol/L.
- Day 504 (ECOG 0): M Protein 5.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.55 mg/dL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 1.83 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 92 µmol/L; Calcium 2.36 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 5.1 mmol/L.
- Day 623 (ECOG 0): M Protein 6.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.81 mg/dL; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.25 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 79 µmol/L; Calcium 2.26 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 5.2 mmol/L.
- Day 710 (ECOG 0): M Protein 5.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.54 mg/dL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.17 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 93 µmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 4.8 mmol/L.
- Day 822 (ECOG 0): M Protein 3.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.98 mg/dL; Immunoglobulin G 16.2 g/L; Immunoglobulin A 5.48 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.11 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 94 µmol/L; Calcium 2.31 mmol/L; Albumin 39 g/L; Total Protein 7.5 g/dL; Glucose 5.1 mmol/L.
- Day 896 (ECOG 0): M Protein 3.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.24 mg/dL; Immunoglobulin G 16.6 g/L; Immunoglobulin A 6.42 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.33 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 106 µmol/L; Calcium 2.17 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 4.8 mmol/L.
- Day 1,029 (ECOG 0): M Protein 5.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.93 mg/dL; Immunoglobulin G 17.7 g/L; Immunoglobulin A 5.99 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.29 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 103 µmol/L; Calcium 2.32 mmol/L; Albumin 36 g/L; Total Protein 7.3 g/dL; Glucose 4.9 mmol/L.

Other clinical attributes
- Day -6: Weight: 94 kg; Height: 176 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2007_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2007_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
